Gene-level copy-number profile of tumor specimen CUPP-B52A-TTM1-A from CCG case CUPP-B52A, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 56.4 years (20,592 days).
Specimen CUPP-B52A-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70945a1e-0a59-4296-8b54-fed1d66ecc21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B52A-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/fec131e0-8e37-4d9a-bda5-18d34a38fdbe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 1,488; copy number 3: 74; copy number 4: 54,457; copy number 5: 32; copy number 6: 62; copy number 7: 2,267; copy number 8: 2; copy number 9: 6; copy number 10: 1; copy number 11: 2; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:71,814,045–71,821,548, 1 gene (within-gene range 0–1): ZNF705E.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:88,477,828–88,498,676, 2 genes, copy number 9: RN7SL583P, AC093578.1.
- chr2:89,252,211–89,254,015, 2 genes, copy number 11: IGKV3-31, IGKV1-32.
- chr21:45,376,191–45,379,635, 2 genes, copy number 16: MTCO1P3, BX322559.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
